Somatic mutation profile of tumor specimen MBCProject_0067_T2_WES (aliquot MBCProject_0067_T2_WES_1) from CMI case MBCProject_0067, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 48.8 years (17,835 days).
Specimen MBCProject_0067_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8670f3dc-2fc5-4242-ab32-aa01a327175d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0067_SALIVA (Saliva), aliquot MBCProject_0067_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17b9a182-28c5-413d-809d-2d6107d9917f

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Nonsense Mutation 4, Frame Shift Ins 3, RNA 2, 5'UTR 2, Intron 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs201105250, COSV61362457; called by muse, mutect2, varscan2
- AMOTL2 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs765734570, COSV51439072; called by muse, mutect2, varscan2
- ATAD2 | c.825T>A p.D275E | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs149531312; called by muse, varscan2
- BAP1 | c.670C>T p.H224Y | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV56243623; called by muse, mutect2, varscan2
- CAMKK2 | c.1188G>A p.M396I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV61213013; called by muse, mutect2, varscan2
- DISP2 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs780892506, COSV99140734; called by muse, mutect2, varscan2
- KMT2C | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 25/129 reads (19%) | catalogued as COSV51484848; called by muse, mutect2, varscan2
- PCDHGA4 | c.1214G>A p.S405N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs1482205004; called by muse, mutect2, varscan2
- SIGLEC9 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as rs757637187, COSV51583241; called by muse, mutect2, varscan2
- ULK1 | c.2568C>A p.H856Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs143735595; called by muse, mutect2, varscan2
- ACKR3 | c.972C>G p.Y324* | Nonsense Mutation (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- ANK3 | c.10265A>T p.D3422V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ANKRD62 | c.1723A>G p.I575V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.066); called by mutect2, varscan2
- CDC40 | c.352G>C p.A118P | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- CDKAL1 | c.1660C>T p.Q554* | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | called by muse, mutect2, varscan2
- FMN2 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LRIF1 | c.2099A>T p.H700L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP2K4 | c.222_225del p.X74_splice | Splice Site (DEL) | VAF 12/20 reads (60%) | called by mutect2, pindel, varscan2
- MROH5 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, varscan2
- MTOR | c.6652A>G p.K2218E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- PIP5K1B | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- PLEKHM3 | c.248C>A p.T83N | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PTEN | c.20_21insTT p.E7Dfs*2 | Frame Shift Ins (INS) | VAF 71/355 reads (20%) | called by mutect2, pindel, varscan2
- PTEN | c.662dup p.V222Gfs*21 | Frame Shift Ins (INS) | VAF 39/166 reads (23%) | called by mutect2, pindel, varscan2
- STARD9 | c.13256C>A p.S4419* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2
- TADA1 | c.56dup p.D21Gfs*9 | Frame Shift Ins (INS) | VAF 19/94 reads (20%) | called by mutect2, pindel, varscan2
- CYP2R1 | c.375C>G p.L125= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs145794885; called by muse, mutect2
- MPEG1 | c.1311A>T p.R437= | Silent (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- NIBAN2 | c.1608G>T p.T536= | Silent (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.1956C>A p.I652= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV55341222; called by muse, mutect2, varscan2
- TBC1D9 | c.111C>T p.G37= | Silent (SNP) | VAF 51/152 reads (34%) | catalogued as rs779300579; called by muse, mutect2, varscan2
- HSD3BP2 | n.232T>C | RNA (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- IMPDH2 | c.-23C>T | 5'UTR (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- KLC1 | c.*1935C>T | 3'UTR (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2
- KLF3-AS1 | n.702+896C>T | Intron (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- SEC61A1 | c.-29C>T | 5'UTR (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- SNORD116-26 | n.26del | RNA (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
